Gene-level copy-number profile of tumor specimen C3L-05326-54 from CPTAC case C3L-05326, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 70.0 years (25,568 days).
Specimen C3L-05326-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 138eeb3c-91c6-4f2f-afcc-a3794bff5bf8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05326-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/7ed42439-828d-4aed-b01a-18a5ae3a3da7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 250; copy number 2: 58,123; copy number 3: 22; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:150,322,639–150,338,156, 2 genes (within-gene range 0–2): ZBED6CL, LRRC61.
- chr16:48,600,176–48,622,033, 2 genes (within-gene range 0–2): AC023813.2, AC023813.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:20,229,402–20,230,346, 1 gene, copy number 5: OR11H7.

Autosomal genes at a single copy (total copy number 1): 250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
